Surgical pathology report (de-identified scan), TCGA case TCGA-60-2716, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-60-2716-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

SPECIMEN(S):

- A. LEVEL 7 LYMPH NODE
- B. LEVEL 9 LYMPH NODE
- C. LEVEL 10 LYMPH NODE
- D. LEVEL 7 LYMPH NODE
- E. LEFT LUNG
- F. LEVEL 5&6 LYMPH NODE
- G. LEVEL 9 LYMPH NODE

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

LLL NSCLC

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA: Lymph node, level 7, biopsy: Negative for carcinoma.

FSB: Lymph node, level 9, biopsy: Negative for carcinoma.

F. Lung, left, bronchial margin: Negative for carcinoma.

GROSS DESCRIPTION:

A. LEVEL 7 LYMPH NODE

Received fresh labeled [REDACTED] level 7 lymph node is one lymph node, 1.0x0.7x0.3cm.

Submitted in toto in blocks labeled FSA1.

B. LEVEL 9 LYMPH NODE

Received fresh labeled [REDACTED] level 9 lymph node is one lymph node, 1.8x1.2x0.4cm.

Submitted in toto in block FSB1.

C. LEVEL 10 LYMPH NODE

[page 2 of 4]
[REDACTED]

Received in formalin and labeled [REDACTED] level 10 lymph node are 5 pieces of anthracotic and tan soft tissue ranging in size from 0.6 to 1.8cm. The largest piece is bisected and contains 2 possible lymph nodes measuring 0.8 and 1.3cm. Specimen is submitted in toto as follows:

C1: 3 possible lymph nodes

C2: 2 bisected lymph nodes

D. LEVEL 7 LYMPH NODE

Received in formalin and labeled [REDACTED] level 7 lymph node are 4 pieces of mottled black and pink-tan soft tissue, ranging in size from 0.9 to 2.7cm. The largest lymph node is bisected and has a central tan-gray coloration with the cortical region having a black-tan coloration. Specimen is submitted in toto as follows:

D1: 2 lymph nodes

D2: an aggregate of multiple lymph nodes

D3: large bisected lymph node

E. LEFT LUNG

Received fresh for tissue procurement and labeled as left lung is a 405gm left lung measuring 21x15x5.8cm with attached bronchus measuring 3.0 cm in length 1.5cm in diameter. A firm subpleural, central mass is palpable with unremarkable overlying pleura. This pleural surface is inked black. Cut section shows a yellow-tan necrotic mass measuring 4.5x3.0x2.5cm. Sectioning through the bronchial tree shows the tumor invading the bronchus at 1.5cm from the bronchial margin. This mass is seen involving both upper and lower lobes of the lung. The bronchial margin is shaved and submitted for frozen section. An enlarged lymph node is seen adjacent to the bronchus and the mass. It measures 2.7x2.1x0.5cm and has a necrotic tan-black discoloration and appears to be partially replaced by tumor. On further sectioning, approximately 2.3cm from this lymph node, a 2nd lymph node is seen measuring 1.7cm in greatest dimension. It has a black and tan discoloration. The remainder of the lung shows dark red congested parenchyma with no additional lesions. Representative sections are submitted as follows:

FSE1: shaved bronchial margin

E2-E7: mass and bronchi from the lower lobe of lung

E8-E9: unremarkable lower lobe of lung

E10: lymph nodes from lower lobe of lung

E11-E15: mass and bronchi from the upper lobe of lung

E16-E18: lymph nodes from upper lobe of lung

E19-E21: remainder of viable appearing mass

E22-E23: unremarkable upper lobe of lung

F. LEVEL 5 & 6 LYMPH NODE

Received in formalin and labeled [REDACTED] level 5 lymph node is a piece of yellow-tan soft tissue measuring 3.0x1.7x0.5cm. It is bisected and contains 2 lymph nodes measuring 1.4 and 1.5cm. Central region of the lymph node has a red-black coloration with the periphery having a yellow-tan coloration. Specimen is submitted in toto in blocks F1-F2.

G. LEVEL 9 LYMPH NODE

Received in formalin and labeled [REDACTED] level 9 lymph node are two pieces of pink-tan soft tissue measuring 1.2 and 1.7cm in greatest dimension. The larger specimen is bisected and contains a lymph node which is 0.5cm in length. Specimen is submitted in toto in block G1.

[REDACTED]

[page 3 of 4]
DIAGNOSIS:

- A. LYMPH NODE, LEVEL 7, BIOPSY:
- ONE REACTIVE, ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- B. LYMPH NODE, LEVEL 9, BIOPSY:
- ONE REACTIVE, ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- C. LYMPH NODES, LEVEL 10, BIOPSIES:
- FOUR REACTIVE, ANTHRACOTIC LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/4).
- D. LYMPH NODES, LEVEL 7, BIOPSIES:
- SEVEN REACTIVE, ANTHRACOTIC LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/7).
- E. LUNG, LEFT, PNEUMONECTOMY:
- INVASIVE, MODERATELY DIFFERENTIATED, SQUAMOUS CELL CARCINOMA WITH EXTENSIVE NECROSIS AND PAPILLARY FEATURES, CENTRALLY LOCATED AND INVOLVING UPPER AND LOWER LOBES OF LUNG.
- TUMOR SIZE IS 4.5 x 3.0 x 2.5 CM IN GREATEST DIMENSION.
- SIX PERIBRONCHIAL LYMPH NODES, POSITIVE FOR METASTATIC CARCINOMA WITH EXTRANODAL EXTENSION (6/9) (2.0 CM LARGEST METASTATIC FOCUS).
- BRONCHIAL MARGIN FREE OF TUMOR.
- SEE TEMPLATE.
- F. LYMPH NODE, LEVELS 5 & 6, BIOPSY:
- FIVE REACTIVE, ANTHRACOTIC LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/5).
- G. LYMPH NODES, LEVEL 9, BIOPSY:
- ONE REACTIVE, ANTHRACOTIC LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

LUNG NEOPLASM TEMPLATE

Surgical procedure:	Pneumonectomy
Tumor location:	Central, left lower lobe, left upper lobe
Tumor size:	4.5 cm
Tumor type:	Squamous cell carcinoma
Histologic grade:	Moderately differentiated
Angiolymphatic invasion:	Indeterminate
Bronchial margin:	Negative, 1.5 cm from tumor
Visceral pleural involvement:	Absent

[page 4 of 4]
Lymph node involvement:

**N1: Ipsilateral Hilar (Level 10) and/or
Peribronchial (Levels 11-14):**

Positive (6/13)

**N2: Ipsilateral Mediastinal (Levels 1-9)
and/or subcarinal:**

Negative (0/14)

**N3: Contralateral mediastinal/hilar,
Scalene or supraclavicular:**

Negative (0/1)

Non-neoplastic lung: No pathological findings

Pathologic stage: pT2 N1 Mx

Note: Lymph node count is based on lymph nodes examined in this case along with case

Source: NCI Genomic Data Commons file bba2f110-4e7c-467a-ac43-ad793af8a5e2 (TCGA-60-2716.DE896266-23C5-469B-A219-BB523657B822.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).